Somatic mutation profile of tumor specimen 4253f4a4-50b9-409a-b9a8-f94658 (aliquot 4253f4a4-50b9-409a-b9a8-f94658_D6) from CPTAC case 17OV033, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen 4253f4a4-50b9-409a-b9a8-f94658: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84ab6302-1762-4e5d-87ac-5a6a9bfe13ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a2a8e97b-09a2-465c-b585-16e53d (Blood Derived Normal), aliquot a2a8e97b-09a2-465c-b585-16e53d_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39bdafdf-aacb-47a4-91e6-84a09f22c989

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 6, Silent 3, Splice Site 2, Frame Shift Del 2, 5'UTR 1, Splice Region 1, Frame Shift Ins 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 144/172 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CHRM4 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs760504636, COSV59183210; called by muse, mutect2, varscan2
- CMYA5 | c.2921C>A p.S974Y | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV71405298; called by muse, mutect2, varscan2
- COL14A1 | c.3559C>T p.R1187C | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779007548; called by muse, mutect2, varscan2
- CSMD2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs575976489; called by muse, mutect2, varscan2
- GABRB2 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50961975; called by muse, mutect2, varscan2
- INPP5D | c.1438-1G>T p.X480_splice (on ENST00000445964 / NM_001017915.3; = p.X479_splice on NM_005541.5) | Splice Site (SNP) | VAF 68/164 reads (41%) | catalogued as COSV64037765; called by muse, varscan2
- LRRC37B | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs866051622, COSV58954182; called by muse, mutect2, varscan2
- PCNX2 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs374111803; called by muse, mutect2, varscan2
- TARBP1 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs367818085, COSV99242010; called by muse, mutect2, varscan2
- TRABD | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 75/98 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as rs200428739; called by muse, mutect2, varscan2
- TYRP1 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs758839020; called by muse, mutect2, varscan2
- ACAP3 | c.2391G>T p.M797I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, varscan2
- CD109 | c.3626_3630dup p.G1211* | Frame Shift Ins (INS) | VAF 29/106 reads (27%) | called by mutect2, varscan2
- DNAH3 | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- DYNLT3 | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- EXOC2 | c.1320G>T p.T440= | Splice Region (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- FBH1 | c.568G>A p.D190N (on ENST00000362091 / NM_178150.3; = p.D241N on NM_032807.4) | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FNIP1 | c.2629A>C p.N877H | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LTBP2 | c.1049_1051del p.K350del | In Frame Del (DEL) | VAF 141/212 reads (67%) | called by pindel, varscan2
- NBN | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NELL2 | c.1354_1369del p.R452Vfs*321 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- NUF2 | c.1391C>A p.T464N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- OR5D13 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SLITRK3 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 121/610 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPAG1 | c.2459del p.K820Rfs*10 | Frame Shift Del (DEL) | VAF 57/234 reads (24%) | called by mutect2, pindel, varscan2
- UNC13A | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 145/377 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MRGPRE | c.630C>T p.P210= | Silent (SNP) | VAF 96/132 reads (73%) | catalogued as rs1199546646; called by muse, mutect2, varscan2
- SBF1 | c.4821G>T p.R1607= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- TLR8 | c.981A>T p.I327= (on ENST00000218032 / NM_138636.5; = p.I345= on NM_016610.4) | Silent (SNP) | VAF 54/78 reads (69%) | called by muse, mutect2, varscan2
- CEP120 | c.-6_-1delinsAA | 5'UTR (DEL) | VAF 23/108 reads (21%) | called by pindel, varscan2*
- COPS7A | c.-44+96C>A | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- NPEPL1 | c.1302+20C>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs934634887; called by muse, varscan2
- PCCB | c.373-1279C>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- RAD51B | c.1036+28923C>A | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- RNF217-AS1 | n.3589C>T | RNA (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- SAYSD1 | c.208-3581A>G | Intron (SNP) | VAF 43/123 reads (35%) | catalogued as rs1428429772; called by muse, mutect2, varscan2
- SZRD1 | c.52-3790C>A | Intron (SNP) | VAF 93/126 reads (74%) | called by mutect2, varscan2
